Gene-level copy-number profile of tumor specimen TCGA-D3-A8GR-06A from TCGA case TCGA-D3-A8GR, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.0 years (23,747 days).
Specimen TCGA-D3-A8GR-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.b28e1628-e264-4ca0-a37c-a1317018ea85.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A8GR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b0361ff1-abc1-448c-9d15-69c131e075df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 9,972; copy number 2: 41,841; copy number 3: 6,511; copy number 4: 1,154; copy number 5: 5; copy number 6: 292; copy number 8: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A8GR-06A-11D-A371-01): tumor purity 0.8, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:182,143,987–182,803,024, 1 gene (within-gene range 0–2): TENM3.
- chr4:182,548,659–182,773,931, 4 genes: RNU2-34P, RN7SKP67, AC079226.2, AC079226.1.
- chr9:16,203,935–16,870,843, 4 genes (within-gene range 0–1): C9orf92, BNC2, AL449983.1, AL450003.1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,892,188–22,214,672, 11 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr11:109,355,085–110,296,712, 11 genes (within-gene range 0–1): AP003049.2, C11orf87, AP003049.1, AP003102.1, LINC02715, RDX, TFAMP2, AP001981.2, RPSAP50, AP001981.1, AP001889.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 301 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:103,926,567–117,365,473, 296 genes, copy number 6–8 (broad region; genes not listed).
- chr11:6,713,536–6,799,689, 5 genes, copy number 5: GVINP1, GVINP2, OR2AG2, OR2AG1, OR6A2.

Autosomal genes at a single copy (total copy number 1): 9,972. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
